Somatic mutation profile of tumor specimen TCGA-SH-A7BD-01A (aliquot TCGA-SH-A7BD-01A-11D-A34C-32) from TCGA case TCGA-SH-A7BD, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Epithelioid mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage IV; Age at diagnosis: 68.5 years (25,019 days).
Specimen TCGA-SH-A7BD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 26e955fa-ad0a-4582-8cd6-def49aab3a85.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SH-A7BD-10A (Blood Derived Normal), aliquot TCGA-SH-A7BD-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/73d6cfdf-b735-4a2f-9916-3f62955260a9

The open-access MAF lists 20 somatic variants for this specimen: 16 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Ins 2, Silent 2, Frame Shift Del 1, RNA 1, 5'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCL9 | c.2528G>A p.R843Q | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.022); catalogued as rs782249357; called by muse, mutect2
- DIAPH1 | c.197C>T p.S66F | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.804); catalogued as rs1414699859, COSV53886714; called by muse, mutect2, varscan2
- RADX | c.973A>G p.T325A | Missense Mutation (SNP) | VAF 26/29 reads (90%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs780973470; called by muse, mutect2, varscan2
- TRMT13 | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV64502316; called by muse, mutect2, varscan2
- AKT3 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- CAPN3 | c.1426G>A p.V476M | Missense Mutation (SNP) | VAF 49/122 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CCT5 | c.677del p.K226Rfs*3 | Frame Shift Del (DEL) | VAF 26/81 reads (32%) | called by mutect2, pindel, varscan2
- CEP85 | c.2233A>C p.T745P | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DSCAML1 | c.3449C>T p.P1150L (on ENST00000321322; = p.P1090L on NM_020693.4) | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NMNAT2 | c.525dup p.V176Cfs*3 | Frame Shift Ins (INS) | VAF 25/49 reads (51%) | called by mutect2, pindel, varscan2
- NR4A2 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 52/115 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- PPP1R9A | c.1205A>G p.N402S | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SHD | c.292G>T p.E98* | Nonsense Mutation (SNP) | VAF 21/36 reads (58%) | called by muse, mutect2, varscan2
- STING1 | c.371T>A p.L124Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- TEX9 | c.533A>G p.D178G | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.425); called by muse, mutect2, varscan2
- VMP1 | c.1183dup p.I395Nfs*12 | Frame Shift Ins (INS) | VAF 28/77 reads (36%) | called by mutect2, pindel, varscan2
- DST | c.4488G>A p.Q1496= (on ENST00000361203 / NM_001374722.1; = p.Q1170= on NM_015548.5) | Silent (SNP) | VAF 24/56 reads (43%) | catalogued as COSV55040741; called by muse, mutect2, varscan2
- SLC35E3 | c.141C>G p.T47= | Silent (SNP) | VAF 89/198 reads (45%) | catalogued as COSV57493990; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503607 del AAA | 5'Flank (DEL) | VAF 25/69 reads (36%) | catalogued as rs771478626; called by mutect2, pindel, varscan2
- SSPOP | n.1339G>A | RNA (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
